Surgical pathology report (de-identified scan), TCGA case TCGA-TM-A84T, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site The University of New South Wales, specimen TCGA-TM-A84T-01A (Primary Tumor).

[page 1 of 4]
Histopathology Report

Case:
Collected:
Ordered by

CLINICAL DETAILS

Left frontal brain tumour. Histopathology. (1) Biopsy. (2) CUSA content.

MACROSCOPIC DESCRIPTION

1. LABELLED 'LEFT FRONTAL TUMOUR (CUSA)'. Multiple tiny fragments of soft pale tan and white tissue. 1A and 1B representative sections (approximately 70% of tissue embedded).
2. LABELLED 'LEFT FRONTAL TUMOUR'. Multiple soft fragments of white and tan tissue, from 3 to 10mm across. 2A tissue all embedded.

MICROSCOPIC REPORT

1&2. SYNOPTIC REPORT FOR BRAIN AND SPINAL CORD NEOPLASMS
EXCLUDING PITUITARY NEOPLASM

1. Type of specimen: Open excision.
2. Biopsy site: Left frontal lobe.
3. Size of specimen: Fragments of brain tissue up to 30mm in aggregate.
4. TUMOUR:

Histological type: Mixed oligoastrocytoma (diffuse variant).

WHO grade: Grade 2.

Size: Not assessable.

Mitoses: Absent.

Vascular proliferation: Absent.

Necrosis: Absent.

Vascular invasion: Not applicable.

Invasion of adjacent structures: Not applicable.

5. Margins or resection: Not assessable.

6. Additional features:

The tumour cells are strongly positive with IDH1. GFAP is generally strong, but with variable staining of individual tumour cells. Vimentin and S100 show variable staining.

Ki67 shows a low proliferation index (in the order of 2-3% in the highest areas).

7. The tissue block considered most suitable for genetic/molecular testing is: 2A.

ICD-O-3
Oligoastrocytoma, grade II 9382/3
Site ^{CHF} Brain, supratentorial NOS C71.0
Ex Brain, frontal lobe C71.1
GW 10/30/13

[page 2 of 4]
Histopathology Report

Case

Collected:

Ordered by:

COMMENT

Arrangement of submission of a request form with consent for 1p/19q deletion testing is recommended.

SUMMARY

1&2. Brain tissue from left frontal lobe - Oligoastrocytoma (WHO grade 2).

REPORTED BY:

[page 3 of 4]
Histopathology Supplementary

Case
Collector
Ordered by:

SUPPLEMENTARY MACROSCOPIC DESCRIPTION

MRN:
Request:

Collected:
Received:

ANATOMICAL PATHOLOGY

OUTSIDE SLIDES HISTOLOGY

Accession:

SOURCE OF MATERIAL:

MATERIAL RECEIVED:

Block: x1 2A) Left frontal tumour.

CLINICAL DETAILS:

Oligoastrocytoma (WHO grade 2). FISH analysis for 1p/19q LOH performed at request of

RESULTS:

This case was analysed for 1p/19q LOH using dual colour probe sets 1p36/1q25 and 19q13/19p13. Cut-off values were adopted from Smith et al. 2000 (J Clin Oncol: 18:636-645) who defined a 1p/1q ratio of <0.85 and a 19q/19p ratio of <0.9 as indicating LOH. The case was also hybridised with EGFR/Cep7 dual colour probe pair to assess whether amplification of EGFR was present.

Chromosome 1

Mean copies 1p per cell: 2.52

Mean copies 1q per cell: 2.19

1p/1q ratio: 1.15

Interpretation: No evidence of 1p loss.

[page 4 of 4]
Histopathology Supplementary Report

Case:
Collected:
Ordered by:

Chromosome 19

Mean copies 19p per cell: 2.15

Mean copies 19q per cell: 2.0

19p/19q ratio: 1.08

Interpretation: No evidence of 19q loss.

EGFR:

Mean copies of EGFR per cell: 2.42

Mean copies cep7 per cell: 2.48

EGFR/cep7 ratio: 0.98

Interpretation: No evidence of EGFR amplification.

COMMENT:

-

CONCLUSION: Negative for both 1p/19q loss and EGFR amplification.

T- A0100 P3-70750

Reported by:

Verified by:

SUPPLEMENTARY SUMMARY

Negative for both 1p/19q loss and EGFR amplification.

REPORTED BY

HPA Discrepancy		☒

Source: NCI Genomic Data Commons file 93abf8a2-9311-49e9-b36d-916d807eac8b (TCGA-TM-A84T.67FE0A94-A6DF-4213-B6DF-CF868FB47E79.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).